CCDI case PBBLZZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3039138a-510a-471a-ac3c-848a1985ae23

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.1 years (2,592 days).

Biospecimens (3 samples)
- Sample 0DC62X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DC635: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC63B: Tissue type: Tumor; Specimen type: Solid Tissue.
